Gene-level copy-number profile of tumor specimen TCGA-GV-A3QF-01A from TCGA case TCGA-GV-A3QF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.1 years (28,890 days).
Specimen TCGA-GV-A3QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2b21ad93-9333-432d-b8ec-8e1359744d1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3QF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd8572ca-8e74-4a79-93c8-8e94934d84ea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 146; copy number 2: 16,294; copy number 3: 20,305; copy number 4: 14,421; copy number 5: 4,677; copy number 6: 2,687; copy number 7: 1,126; copy number 8: 5; copy number 61: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3QF-01A-31D-A22Y-01): tumor purity 0.54, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–31,506,615, 91 genes (broad region; genes not listed).
- chr10:59,788,747–59,960,913, 2 genes (within-gene range 0–2): CCDC6, LINC01553.
- chr10:60,050,668–60,060,743, 1 gene: AL592430.1.
- chr17:22,420,022–22,706,703, 20 genes: AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,141 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:92,832,737–92,961,522, 1 gene, copy number 7 (within-gene range 5–7): DIPK1A.
- chr1:92,930,696–109,426,448, 244 genes, copy number 7 (broad region; genes not listed).
- chr1:110,653,560–110,764,506, 3 genes, copy number 7: AL365361.1, KCNA3, Y_RNA.
- chr1:160,151,586–167,166,479, 191 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:19,910,263–20,246,387, 12 genes, copy number 7 (within-gene range 4–7): WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P.
- chr3:187,932,764–188,147,310, 5 genes, copy number 8 (within-gene range 6–8): AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1.
- chr7:54,721,724–55,344,958, 10 genes, copy number 61: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr10:44,712–38,783,108, 675 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
